CCDI case PBCJRM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0e216c24-f8e3-4159-90d2-a4cfe85457a7

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,145 days).

Biospecimens (3 samples)
- Sample 0DTPME: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3LP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU3MF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
